Gene-level copy-number profile of tumor specimen TCGA-LN-A49M-01A from TCGA case TCGA-LN-A49M, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 62.8 years (22,933 days).
Specimen TCGA-LN-A49M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.6f470427-e9a5-4eac-91f7-c880cabdeaa5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/1d08944f-19d0-4ad8-9fa8-5b2af6082994

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 15,792; copy number 2: 40,840; copy number 3: 2,736; copy number 4: 241; copy number 5: 93; copy number 8: 15; copy number 10: 37; copy number 15: 28; copy number 29: 6.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr4:40,990,154–40,990,273, 1 gene: RNA5SP160.
- chr5:95,962,001–96,631,085, 1 gene (within-gene range 0–1): AC104123.1.
- chr5:96,210,121–96,779,595, 5 genes (within-gene range 0–1): RNU6-524P, AC099509.1, AC099509.2, PCSK1, CAST.
- chr9:17,134,982–17,503,923, 2 genes (within-gene range 0–1): CNTLN, SAMM50P1.
- chr18:39,314,240–39,335,672, 2 genes: AC011139.1, RPL7AP66.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 179 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,048,932–71,629,421, 70 genes, copy number 5–10 (broad region; genes not listed).
- chr12:24,566,964–29,784,759, 109 genes, copy number 5–29 (within-gene range 2–31) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
